Gene-level copy-number profile of tumor specimen ALCH-B3AE-TTP1-A from ALCHEMIST case ALCH-B3AE, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,079 days).
Specimen ALCH-B3AE-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 16698443-fc70-401d-a52d-7bf2ec9cb1c2.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B3AE-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/9e5361f1-ff2e-4cd9-8eb4-a37bf6da6569

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 105; copy number 1: 4,965; copy number 2: 52,896; copy number 3: 801; copy number 4: 122; copy number 5: 8; copy number 6: 7; copy number 9: 2; copy number 11: 1; copy number 15: 3.

Homozygous deletions (total copy number 0; autosomes only): 101 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,014,028–16,057,308, 4 genes: HSPB7, CLCNKA, AL355994.2, CLCNKB.
- chr2:2,729,908–2,730,957, 1 gene: AC018685.1.
- chr3:128,462,439–128,493,201, 3 genes (within-gene range 0–2): DNAJB8, DNAJB8-AS1, GATA2.
- chr4:8,745,391–8,871,839, 3 genes: AC209005.1, HMX1, AC116612.1.
- chr5:139,644,460–139,645,002, 1 gene: AC113361.1.
- chr5:139,648,999–139,649,728, 1 gene (within-gene range 0–2): CXXC5-AS1.
- chr6:34,466,061–34,556,333, 2 genes (within-gene range 0–2): PACSIN1, SPDEF.
- chr7:128,830,406–128,862,626, 2 genes (within-gene range 0–2): FLNC, FLNC-AS1.
- chr9:123,356,170–123,380,324, 1 gene (within-gene range 0–2): CRB2.
- chr9:123,402,525–123,493,156, 3 genes (within-gene range 0–2): MIR601, MIR7150, AL445489.1.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:130,892,707–130,896,812, 1 gene: QRFP.
- chr9:131,096,476–131,123,152, 1 gene: AIF1L.
- chr9:137,224,635–137,226,315, 1 gene: CYSRT1.
- chr10:49,610,310–49,612,720, 1 gene (within-gene range 0–1): SLC18A3.
- chr14:92,923,150–93,138,465, 4 genes: CHGA, ITPK1, ITPK1-AS1, CYB5AP3.
- chr15:25,170,723–25,257,027, 45 genes (within-gene range 0–2): SNORD115-1, SNORD115-2, SNORD115-3, SNORD115-4, SNORD115-5, SNORD115-6, SNORD115-7, SNORD115-8, SNORD115-9, SNORD115-10, SNORD115-11, SNORD115-12, SNORD115-13, SNORD115-14, SNORD115-15, SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19, SNORD115-20, SNORD115-21, SNORD115-22, SNORD115-23, SNORD115-24, SNORD115-25, SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.
- chr15:77,525,540–77,534,110, 1 gene: AC046168.1.
- chr16:75,204,103–75,286,800, 6 genes: CTRB2, CTRB1, AC009078.2, BCAR1, AC009078.3, RNU6-758P.
- chr16:81,100,875–81,220,370, 3 genes (within-gene range 0–2): PKD1L2, RNU6-1191P, AC092718.9.
- chr17:142,789–386,254, 7 genes: DOC2B, LINC02091, RPH3AL, AC129507.4, AC129507.1, AC129507.2, AC129507.3.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–2): AC127024.7, AC127024.3, AC127024.2.
- chr17:45,999,250–45,999,694, 1 gene (within-gene range 0–1): STH.
- chr19:33,208,664–33,225,850, 2 genes (within-gene range 0–1): SLC7A10, AC008738.4.
- chr21:43,358,147–43,366,566, 2 genes: LINC01679, AP001046.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 21 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:242,175,181–242,175,634, 1 gene, copy number 11: RPL23AP88.
- chr7:76,524,515–76,541,459, 2 genes, copy number 6–9: AC004980.3, SPDYE16.
- chr9:136,779,939–136,829,466, 7 genes, copy number 5–6 (within-gene range 3–6): ATP6V1G1P3, TMEM141, AL355987.3, CCDC183, AL355987.4, AL355987.2, CCDC183-AS1.
- chr9:136,812,788–136,815,536, 1 gene, copy number 6 (within-gene range 3–6): NCLP1.
- chr9:136,844,415–136,848,801, 1 gene, copy number 6 (within-gene range 3–10): AJM1.
- chr19:1,103,926–1,106,791, 1 gene, copy number 5: GPX4.
- chr19:1,248,553–1,279,244, 4 genes, copy number 5: MIDN, CIRBP, CIRBP-AS1, FAM174C.
- chr21:44,133,610–44,210,114, 4 genes, copy number 9–15 (within-gene range 2–15): GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 2,117. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
